Somatic mutation profile of tumor specimen TARGET-10-PARFIZ-09A (aliquot TARGET-10-PARFIZ-09A-01D) from TARGET case TARGET-10-PARFIZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,621 days).
Specimen TARGET-10-PARFIZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c95b643-a69e-4d37-bcae-f2a71689bc99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFIZ-10A (Blood Derived Normal), aliquot TARGET-10-PARFIZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/989c938e-9776-431c-b138-bef04bf3ca73

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Splice Region 2, Silent 2, In Frame Del 1, 5'UTR 1, Nonsense Mutation 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP8B2 | c.2796C>T p.T932= (on ENST00000672630; = p.T899= on NM_001367934.1 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 40/103 reads (39%) | catalogued as rs781532937; called by muse, mutect2, varscan2
- CD80 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 89/204 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs780121133, COSV99958236; called by muse, mutect2, varscan2
- CROCC2 | c.3899G>A p.R1300H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as rs185202027; called by muse, mutect2, varscan2
- FGFR2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV60643607; called by muse, mutect2, varscan2
- OR10S1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV101602445; called by muse, mutect2, varscan2
- RORB | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs892503579; called by muse, mutect2, varscan2
- SLC35F1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs775023281; called by muse, mutect2, varscan2
- SYT13 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs1235313234; called by muse, mutect2, varscan2
- TBCE | c.1209G>A p.P403= (on ENST00000366601; = p.P466= on NM_003193.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 115/294 reads (39%) | catalogued as rs762799965, COSV64005273; called by muse, mutect2, varscan2
- TLN1 | c.5672G>A p.S1891N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1389990010; called by muse, mutect2, varscan2
- TUBAL3 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 44/138 reads (32%) | catalogued as rs143994010; called by muse, mutect2, varscan2
- IGKV4-1 | chr2:88886149 del CTC | In Frame Del (DEL) | VAF 26/63 reads (41%) | called by pindel, varscan2
- SGMS1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D12 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2orf42 | c.1191T>C p.D397= | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- MATK | c.918C>T p.H306= (on ENST00000310132 / NM_139355.3; = p.H307= on NM_002378.4) | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV59556039; called by muse, mutect2, varscan2
- ASIC2 | c.555+118435C>T | Intron (SNP) | VAF 21/42 reads (50%) | catalogued as COSV63312541, COSV63325297; called by muse, mutect2, varscan2
- CYHR1 | c.-102G>T | 5'UTR (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2
- IGHV1-45 | chr14:106506995 ins GGTGCGGAA | 3'Flank (INS) | VAF 33/95 reads (35%) | called by mutect2, pindel, varscan2
